Gene-level copy-number profile of tumor specimen ALCH-AE71-TTP1-A from ALCHEMIST case ALCH-AE71, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.0 years (21,926 days).
Specimen ALCH-AE71-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0e7e3f7-4cb0-4038-9362-b647ed48e6c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE71-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/990589ec-bfff-4bfb-b8fd-6381151cd8d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 6,815; copy number 2: 50,608; copy number 3: 1,273; copy number 4: 90; copy number 5: 12; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,874,696–84,875,020, 1 gene (within-gene range 0–2): RPL12P18.
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr3:101,458,530–101,458,626, 1 gene (within-gene range 0–2): Y_RNA.
- chr4:105,293,664–105,293,946, 1 gene: RN7SL89P.
- chr6:170,615,515–170,738,536, 1 gene (within-gene range 0–2): AL672310.1.
- chr6:170,695,313–170,737,777, 2 genes: AL731661.1, AL731684.1.
- chr7:5,475,804–5,563,902, 5 genes (within-gene range 0–2): AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1.
- chr7:45,789,585–45,843,740, 5 genes: RNU6-241P, CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:46,277,662–46,386,608, 5 genes: CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr13:45,333,471–45,417,975, 7 genes (within-gene range 0–2): TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:30,624,413–30,702,775, 3 genes (within-gene range 0–2): SH3GL1P2, LRRC37BP1, RN7SL316P.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–2): AC127024.7, AC127024.3, AC127024.2.
- chr19:19,512,418–19,546,659, 5 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,915,868–84,916,660, 1 gene, copy number 5: RPS2P17.
- chr2:197,486,584–197,516,737, 2 genes, copy number 6 (within-gene range 2–6): HSPD1, HSPE1.
- chr3:185,914,558–185,938,103, 1 gene, copy number 6: TRA2B.
- chr5:135,802,985–135,803,075, 1 gene, copy number 5: MIR5692C1.
- chr16:10,718,633–10,725,296, 8 genes, copy number 5: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr16:84,119,293–84,121,153, 1 gene, copy number 5: AC040169.2.
- chr19:7,037,748–7,040,179, 1 gene, copy number 5: MBD3L4.
- chr22:18,873,543–18,894,407, 2 genes, copy number 6: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 4,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
